Somatic mutation profile of tumor specimen MBCProject_1160_T2_WES (aliquot MBCProject_1160_T2_WES_1) from CMI case MBCProject_1160, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 29.8 years (10,901 days).
Specimen MBCProject_1160_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Soft Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 832cf6c7-c1d7-4328-a6ec-431b3e509587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1160_SALIVA (Saliva), aliquot MBCProject_1160_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8582c59-8ca2-47c5-b977-561face9c595

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 3, 5'UTR 2, 3'Flank 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RP1 | c.2950G>A p.D984N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV55116542; called by muse, mutect2
- RP1 | c.2951A>C p.D984A | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.122); catalogued as CM056381; called by muse, mutect2
- AMPD2 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANKRD26 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- AP1B1 | c.2110G>C p.D704H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- C1orf131 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- CPT1B | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, varscan2
- CPT1B | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DENND6B | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAAF5 | c.1340C>G p.T447R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FLG | c.10579G>C p.A3527P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); called by muse, mutect2
- JMJD8 | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KCNV2 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LSM10 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LTBP3 | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2
- MTR | c.3786T>G p.Y1262* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- NXF1 | c.313A>T p.R105* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- NXF1 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA1 | c.883T>A p.Y295N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB3GAP1 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SEPTIN9 | c.1309G>T p.V437F (on ENST00000427177 / NM_001113491.2; = p.V419F on NM_006640.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC13D | c.2404C>A p.L802I | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRIA3 | c.2619C>T p.N873= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs771170173; called by muse, mutect2
- GSE1 | c.1134G>A p.E378= | Silent (SNP) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- RADIL | c.132C>T p.S44= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- ZFPL1 | c.732G>C p.L244= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs780217595; called by muse, mutect2, varscan2
- CDKN2A | chr9:21967318 G>A | 3'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as rs768959694; called by mutect2, varscan2
- HSDL2 | c.-9A>G | 5'UTR (SNP) | VAF 14/22 reads (64%) | catalogued as rs747910175; called by muse, mutect2
- KATNBL1 | c.883-623C>G | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- LAMA1 | c.-43C>T | 5'UTR (SNP) | VAF 10/17 reads (59%) | catalogued as rs758867374; called by mutect2, varscan2
- ZNF48 | chr16:30395284 C>G | 5'Flank (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
